Surgical pathology report (de-identified scan), TCGA case TCGA-B3-3926, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B3-3926-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN

- A. Left renal mass
- B. Deep margin left renal
- C. Perinephric fat
- D. Left kidney

CLINICAL NOTES

CLINICAL HISTORY: Renal mass

FROZEN SECTION DIAGNOSIS

- A. Diagnosis deferred to permanent sections.
- B. Tumor present on one aspect of specimen on two of three blocks on frozen section.

GROSS DESCRIPTION

A. Received fresh for frozen section and for tissue procurement labeled "left renal mass" is a disrupted specimen, with a soft tan-pink fragment of tumor, 3.2 x 3 x 2 cm. This is focally attached to a disrupted thin rim of circular maroon-brown renal tissue, 5 cm in length x 0.6 x 0.5 cm. There is also attached fatty tissue, 6 x 1.5 x 1 cm in aggregate. The margins are indeterminate due to specimen disruption. A portion of tumor and of normal are submitted for tissue procurement. One block is submitted for frozen section diagnosis. Six additional blocks, including all of the tumor, are submitted for permanent sections.

B. Received fresh for frozen section, labeled "deep margin left renal" is a circular cross section of maroon-brown kidney tissue, 4 x 3 cm, and 0.5 cm thick. On one aspect there is some pale tissue, which may represent tumor. The entire specimen is submitted in three blocks for frozen section diagnosis.

C. Received fresh labeled "perinephric fat" is a 6.6 x 6.3 x 2.6 cm. aggregate of soft lobulated yellow adipose tissue. The cut surfaces are homogenous, glistening, and yellow.

GROSS DESCRIPTION

RS-3.

D. Received fresh labeled "left kidney" is a 289 gram, 10.5

x 6.5 x 3.5 cm, kidney, with attached probe patent 7.5 cm. long segment of ureter averaging 0.3 cm. in diameter. A scant amount of predominantly torn golden yellow perirenal adipose tissue is present. A wedge-shaped 4.8 x 2.5 cm. defect is present along

[page 2 of 4]
[REDACTED]

the lateral/central aspect of the specimen. Multiple sutures and packing gauze are present. The cauterized margin of the defect is inked orange for identification purposes. A scant amount of presumptive residual lesion measuring 0.9 x 0.5 x 0.5 cm. is presumptively identified within the central surgical defect. The renal pelvis is smooth, glistening, and tan-white. The uninvolved parenchyma is uniform and tan, with a well-defined corticomedullary junction, with a maximal cortical thickness of 1.2 cm. No additional abnormality is identified grossly. No adrenal tissue is present. RS-10, following fixation.

BLOCK SUMMARY: D1 - vascular and ureteral margins; D2-D5 - resection site, with possible residual lesion; D6-D8 - additional sections from wedge resection site; D9,D10 - random from remainder of specimen.

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

For confirmation in the interpretation in this case, this case was sent in consultation to [REDACTED] M.D. of the [REDACTED] for his expert opinion. Please see the consultation report from [REDACTED].

[REDACTED] diagnosis for part A, the left renal mass, is: "Papillary renal cell carcinoma, solid variant, Furhman grade III. The tumor is organ confined and measures at least 3.2 cm in this specimen (gross). No angiolymphatic invasion is

MICROSCOPIC DESCRIPTION

seen." [REDACTED] diagnosis for part B, the deep margin, is: "Papillary renal cell carcinoma, similar to that seen in part A. The tumor is organ confined and measures at least 1.5 cm in this specimen (microscopic). No angiolymphatic invasion is seen."

[REDACTED] diagnosis for part C, the perinephric fat, is: "Benign fibroadipose tissue."

[REDACTED] diagnosis for part D, the left completion nephrectomy, is: "Renal parenchyma with cautery artifact. No definitive tumor is identified. Surgical margins including renal, vascular and ureteral margins, are negative for tumor. Non-neoplastic kidney shows mild arteriosclerosis."

In a note regarding his interpretation, [REDACTED] states the following: "NOTE: Staging of this tumor is difficult due to the marked specimen disruption. No definite extrarenal or

[page 3 of 4]
vascular invasion is identified. The distinction between T1a and T1b is best determined clinically. No lymph nodes were sampled (Nx)."

The following template summarizes the findings in this case:

Histologic type: Papillary renal cell carcinoma, solid variant, present in parts A and B. In part D there are some cauterized areas that raise consideration for some residual carcinoma, although Dr.

did not feel there was definitive tumor in this part.

Histologic grade: Fuhrman grade 3

Primary tumor (pT): See discussion above

Margins of resection: There is tumor in part B, the left deep margin, but the surgical margins in the completion nephrectomy, part

D, are negative for tumor.

Regional lymph nodes (pN): pNX

Distant metastasis (pM): pMx

Adrenal gland: Not submitted with specimen

Vascular invasion: Not identified

MICROSCOPIC DESCRIPTION

Non-neoplastic kidney: Mild arteriosclerosis

2,3,4x2,14x2,15x2

DIAGNOSIS

- A. Kidney, left, partial nephrectomy
- Papillary renal cell carcinoma, solid variant, Fuhrman grade 3 (see microscopic description).
- B. Kidney, left, deep margin, excision
- Papillary renal cell carcinoma present, similar to part A (see microscopic description).
- C. Perinephric adipose tissue, left, excision
- Benign fibroadipose tissue.
- D. Kidney, left, completion nephrectomy
- Renal parenchyma with cautery artifact.
- No definitive tumor is identified.
- Surgical margins including renal, vascular and ureteral margins, are negative for tumor.
- Non-neoplastic kidney shows mild arteriosclerosis.

[page 4 of 4]
NOTE: The above diagnoses are rendered per expert consultation from
the [REDACTED] Please see
[REDACTED] microscopic description and the consultation report from Dr.
[REDACTED]
[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 707528da-821b-4620-9664-93f9dafe12dd (TCGA-B3-3926.9B523CAA-0EA8-4FE2-8CC6-A9C7F5EB6558.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).